TCGA case TCGA-H4-A2HO — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Medical College of Georgia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86d1e388-b30f-48fd-9647-3848eb6134f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 53.7 years (19,630 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 46 days.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 46 days; Disease response: Tumor Free.
- ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 177 cm; BMI: 22.

Exposures
- Occupation type: Painters, Building Structure Cleaners and Related Trades Workers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30; Age at onset: 24.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-H4-A2HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 470 mg.
  Slide TCGA-H4-A2HO-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-H4-A2HO-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 480 mg.
- Sample TCGA-H4-A2HO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-H4-A2HO-10A, TCGA-H4-A2HO-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Occupation primary: painter; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Radical Cystoprostatectomy; Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 46 days; disease-specific survival: no event (censored), 46 days; disease-free interval: no event (censored), 46 days; progression-free interval: no event (censored), 46 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-H4-A2HO-01A-11D-A17S-01): tumor purity 0.63, ploidy 2.04, whole-genome doublings 0.
